Gene-level copy-number profile of tumor specimen TCGA-85-8479-01A from TCGA case TCGA-85-8479, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary squamous cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 66.7 years (24,350 days).
Specimen TCGA-85-8479-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.c19dcc06-3bc2-4732-9a53-381a4933e4b6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-8479-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/059ba2ef-2e78-419f-a2b6-d539f19ca65f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 20,943; copy number 2: 32,531; copy number 3: 5,465; copy number 4: 651; copy number 5: 128; copy number 6: 8; copy number 7: 7; copy number 11: 39; copy number 19: 17; copy number 24: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-8479-01A-11D-2322-01): tumor purity 0.67, ploidy 1.76, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:59,314,110–59,529,251, 2 genes: AC008833.1, NDUFB4P2.
- chr6:136,557,046–136,792,477, 4 genes (within-gene range 0–1): MAP3K5, MAP3K5-AS1, RNA5SP219, AL121933.2.
- chr6:137,197,485–137,544,372, 3 genes: IFNGR1, OLIG3, BTF3L4P3.
- chr6:137,995,270–137,996,147, 1 gene: RPSAP42.
- chr12:120,740,470–120,761,592, 1 gene (within-gene range 0–1): AC069234.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 217 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:174,302,944–182,740,848, 128 genes, copy number 5 (broad region; genes not listed).
- chr12:66,251,082–69,959,097, 80 genes, copy number 7–24 (broad region; genes not listed).
- chr12:69,946,543–69,947,081, 1 gene, copy number 7: AC078922.1.
- chr12:71,439,798–71,698,968, 8 genes, copy number 6 (within-gene range 1–6): LGR5, AC090116.1, AC078860.3, AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1.

Autosomal genes at a single copy (total copy number 1): 19,373. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
